Somatic mutation profile of tumor specimen TCGA-ZP-A9CV-01A (aliquot TCGA-ZP-A9CV-01A-11D-A382-10) from TCGA case TCGA-ZP-A9CV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; Tumor grade: G1; Age at diagnosis: 59.2 years (21,633 days).
Specimen TCGA-ZP-A9CV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34a836cd-47c7-4fd1-a288-52fca2005107.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZP-A9CV-10B (Blood Derived Normal), aliquot TCGA-ZP-A9CV-10B-01D-A385-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e96ec070-828f-4633-9cf7-46b223f26d13

The open-access MAF lists 112 somatic variants for this specimen: 87 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 71, Silent 25, Frame Shift Del 7, Nonsense Mutation 5, Splice Region 2, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 33/108 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs121913409, COSV62687872, COSV62688307, COSV62689938, COSV62711475; ClinVar: other / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.650A>G p.Y217C | Missense Mutation (SNP) | VAF 70/231 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as rs777261524, COSV99289285; called by muse, mutect2, varscan2
- ABCC8 | c.151T>C p.W51R | Missense Mutation (SNP) | VAF 32/101 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV100217677; called by muse, mutect2, varscan2
- ADGRF1 | c.1271T>G p.F424C | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV99347576; called by muse, mutect2, varscan2
- AHNAK2 | c.12252G>T p.K4084N | Missense Mutation (SNP) | VAF 55/193 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100318818; called by muse, varscan2
- AP1S2 | c.224A>G p.N75S | Missense Mutation (SNP) | VAF 184/283 reads (65%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.705); catalogued as COSV100236916; called by muse, mutect2, varscan2
- ARHGEF12 | c.198T>C p.Y66= | Splice Region (SNP) | VAF 28/71 reads (39%) | catalogued as COSV100755186; called by muse, mutect2, varscan2
- ARID2 | c.797G>A p.W266* | Nonsense Mutation (SNP) | VAF 60/201 reads (30%) | catalogued as COSV57604977; called by muse, mutect2, varscan2
- ARMCX3 | c.977A>G p.N326S | Missense Mutation (SNP) | VAF 233/282 reads (83%) | SIFT tolerated (0.58); PolyPhen benign (0.089); catalogued as COSV100362332; called by muse, mutect2, varscan2
- ASAP1 | c.1183C>T p.H395Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100727753; called by muse, mutect2, varscan2
- BTN2A2 | c.623C>T p.T208I | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as COSV100760588; called by muse, mutect2, varscan2
- CERS6 | c.1051G>T p.D351Y | Missense Mutation (SNP) | VAF 39/136 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.467); catalogued as COSV99987664; called by muse, mutect2, varscan2
- CUX1 | c.1565G>T p.R522L (on ENST00000437600 / NM_181500.4; = p.R524L on NM_001913.5) | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.193); catalogued as COSV99476629; called by muse, mutect2, varscan2
- DCST2 | c.855G>A p.M285I | Missense Mutation (SNP) | VAF 61/378 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99792225; called by muse, mutect2, varscan2
- DNAJB6 | c.120A>C p.E40D | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.947); catalogued as COSV100055948; called by muse, mutect2, varscan2
- DPYS | c.650A>T p.H217L | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100680078; called by muse, mutect2, varscan2
- EDC4 | c.3526G>A p.G1176S | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated (0.55); PolyPhen benign (0.057); catalogued as COSV100197770; called by muse, mutect2, varscan2
- ERBB2 | c.2944G>T p.D982Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99508940; called by muse, mutect2, varscan2
- EVI2B | c.512C>T p.T171I | Missense Mutation (SNP) | VAF 71/232 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs1177522391, COSV100445647; called by muse, mutect2, varscan2
- GDF11 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV99144074; called by muse, mutect2, varscan2
- GOLGA4 | c.6166G>T p.A2056S | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as COSV100729140; called by muse, mutect2
- GORASP2 | c.1105C>G p.P369A | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV52201766, COSV99304723; called by muse, mutect2, varscan2
- GPR152 | c.89G>C p.G30A | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.096); catalogued as COSV100351645; called by muse, mutect2, varscan2
- HTRA2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs1558611272, COSV99239924; called by muse, mutect2, varscan2
- ITM2A | c.665G>A p.R222K | Missense Mutation (SNP) | VAF 56/288 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1394128672, COSV100964491; called by muse, mutect2, varscan2
- JAK1 | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV100692324; called by muse, mutect2, varscan2
- JAK1 | c.1669G>T p.A557S | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.475); catalogued as COSV100692325; called by muse, mutect2, varscan2
- JRK | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.027); catalogued as rs1554635606, COSV101401154; called by muse, mutect2, varscan2
- KCNH5 | c.26T>C p.V9A | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as COSV100527959; called by muse, mutect2, varscan2
- LAMA2 | c.907A>T p.N303Y | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV101370797; called by muse, mutect2, varscan2
- MGST3 | c.219T>G p.F73L | Missense Mutation (SNP) | VAF 7/182 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV100903367; called by muse, mutect2
- MS4A5 | c.142A>G p.K48E | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as COSV100281102; called by muse, mutect2, varscan2
- MSANTD3 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 50/126 reads (40%) | catalogued as COSV100614960, COSV58490778; called by muse, mutect2, varscan2
- MYH14 | c.5776G>A p.D1926N | Missense Mutation (SNP) | VAF 60/183 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV99223937; called by muse, mutect2, varscan2
- MYH7 | c.5453G>C p.R1818P | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100806544, COSV62517479; called by muse, varscan2
- NFATC1 | c.455C>T p.P152L | Missense Mutation (SNP) | VAF 6/69 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.218); catalogued as COSV99502450; called by muse, mutect2
- NMRAL1 | c.731A>C p.E244A | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV99361915; called by muse, mutect2, varscan2
- NTRK2 | c.1249A>T p.I417F | Missense Mutation (SNP) | VAF 41/162 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV52871377, COSV99458235; called by muse, mutect2, varscan2
- OR4N5 | c.232G>T p.V78F | Missense Mutation (SNP) | VAF 26/114 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs1208613363, COSV100374221; called by muse, mutect2, varscan2
- OR5P3 | c.7A>G p.T3A | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100103261; called by muse, mutect2
- OR6K6 | c.770C>T p.S257L (on ENST00000368144; = p.S233L on NM_001005184.1) | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761000591, COSV100933785; called by muse, mutect2, varscan2
- PASK | c.3163A>G p.I1055V | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.435); catalogued as rs775509775, COSV99300164; called by muse, mutect2, varscan2
- PCDH18 | c.1360C>A p.Q454K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.68); PolyPhen benign (0.338); catalogued as COSV100787497; called by muse, mutect2, varscan2
- PDZK1 | c.403C>G p.L135V | Missense Mutation (SNP) | VAF 200/474 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV100777380; called by muse, mutect2, varscan2
- PDZRN4 | c.1534G>T p.E512* (on ENST00000402685 / NM_001164595.2; = p.E254* on NM_013377.4) | Nonsense Mutation (SNP) | VAF 25/88 reads (28%) | catalogued as COSV100115378; called by muse, mutect2, varscan2
- PURG | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99989784; called by muse, mutect2, varscan2
- RFC2 | c.238A>T p.T80S | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.41); catalogued as COSV99278078; called by muse, mutect2, varscan2
- RIMS1 | c.4138A>G p.T1380A | Missense Mutation (SNP) | VAF 79/234 reads (34%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.952); catalogued as COSV99330104; called by muse, mutect2, varscan2
- RNF133 | c.151C>T p.H51Y | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs749471581, COSV100411745; called by muse, mutect2, varscan2
- RP1L1 | c.5500G>A p.G1834S | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.208); catalogued as COSV101223021; called by muse, mutect2, varscan2
- RPS6KA3 | c.1363A>T p.K455* | Nonsense Mutation (SNP) | VAF 6/68 reads (9%) | catalogued as COSV101084640; called by muse, mutect2
- SEC61A2 | c.707G>T p.R236L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100036626, COSV53651171; called by muse, mutect2, varscan2
- SERTAD4 | c.308A>C p.E103A | Missense Mutation (SNP) | VAF 56/157 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100882662; called by muse, mutect2, varscan2
- SFTA3 | n.939T>A | Splice Region (SNP) | VAF 64/203 reads (32%) | catalogued as COSV101410205; called by muse, mutect2, varscan2
- SH3RF2 | c.1374G>A p.W458* | Nonsense Mutation (SNP) | VAF 43/101 reads (43%) | catalogued as rs1253703202, COSV100768006; called by muse, mutect2, varscan2
- SIN3A | c.1571A>T p.Y524F | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.068); catalogued as COSV100845225; called by muse, mutect2, varscan2
- SLC26A7 | c.1934A>G p.K645R | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.007); catalogued as COSV99404231; called by muse, mutect2, varscan2
- SLC43A1 | c.1169A>G p.Q390R | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV99561203; called by muse, mutect2, varscan2
- SMNDC1 | c.515A>G p.E172G | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100852183; called by muse, mutect2, varscan2
- SNX14 | c.458A>T p.Y153F | Missense Mutation (SNP) | VAF 204/660 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.597); catalogued as COSV100121755; called by muse, mutect2, varscan2
- SPATA20 | c.236A>G p.N79S (on ENST00000356488 / NM_001258372.1; = p.N95S on NM_022827.4) | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50066190, COSV99136622; called by muse, mutect2, varscan2
- SRCAP | c.2935A>G p.T979A | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as COSV99351209; called by muse, mutect2, varscan2
- SYNE2 | c.15213G>T p.W5071C | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100648413; called by muse, mutect2, varscan2
- TENM3 | c.3125G>A p.G1042E | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69300328; called by muse, mutect2
- TEX11 | c.847T>C p.Y283H (on ENST00000344304; = p.Y268H on NM_031276.3) | Missense Mutation (SNP) | VAF 89/146 reads (61%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.833); catalogued as COSV100722175; called by muse, mutect2, varscan2
- TIMELESS | c.3359G>A p.G1120D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.003); catalogued as COSV99974300; called by muse, mutect2, varscan2
- TLE3 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.672); catalogued as COSV58168136; called by muse, mutect2, varscan2
- TNC | c.1153G>A p.G385S | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100406210; called by muse, mutect2, varscan2
- TPD52L1 | c.556A>G p.S186G | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV100509447; called by muse, mutect2, varscan2
- TRAK1 | c.2474A>G p.K825R | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV59642699; called by muse, mutect2
- TRIML2 | c.303T>A p.F101L | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.444); catalogued as COSV100456327; called by muse, mutect2, varscan2
- TSHZ3 | c.1978A>G p.S660G | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99552580; called by muse, mutect2, varscan2
- TTI2 | c.1439T>A p.I480N | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV100659808; called by muse, mutect2, varscan2
- URI1 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 121/393 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.076); catalogued as COSV100369208; called by muse, mutect2, varscan2
- XPO6 | c.107A>G p.N36S | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.371); catalogued as COSV100485331; called by muse, mutect2, varscan2
- ZNF630 | c.1379T>C p.V460A | Missense Mutation (SNP) | VAF 32/54 reads (59%) | SIFT tolerated (0.73); PolyPhen benign (0.025); catalogued as COSV99332571; called by muse, mutect2, varscan2
- ZNF816-ZNF321P | c.389C>T p.T130I | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.331); catalogued as COSV100008478; called by muse, mutect2, varscan2
- ELAC1 | c.44_47del p.P15Lfs*31 | Frame Shift Del (DEL) | VAF 33/104 reads (32%) | called by mutect2, pindel, varscan2
- EPHX1 | c.1250_1284del p.Y417Wfs*8 | Frame Shift Del (DEL) | VAF 28/92 reads (30%) | called by mutect2, pindel
- GPS2 | c.964_976del p.P322Tfs*19 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- MAZ | c.1005del p.K335Nfs*67 | Frame Shift Del (DEL) | VAF 19/55 reads (35%) | called by mutect2, pindel, varscan2
- NCBP1 | c.219_224+19del p.X73_splice | Splice Site (DEL) | VAF 19/63 reads (30%) | called by mutect2, pindel
- RASSF5 | c.364_377del p.G122Rfs*12 | Frame Shift Del (DEL) | VAF 11/102 reads (11%) | called by mutect2, pindel
- RPL22 | c.17del p.K6Sfs*4 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel
- SEC31A | c.1719_1730del p.I573_L577delinsM (on ENST00000355196 / NM_001318120.1; = p.I534_L538delinsM on NM_016211.4) | In Frame Del (DEL) | VAF 49/172 reads (28%) | called by mutect2, pindel, varscan2
- SPATA31A3 | c.491A>T p.D164V | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.161); called by muse, mutect2, varscan2
- TTC13 | c.2117del p.V706Gfs*17 | Frame Shift Del (DEL) | VAF 44/120 reads (37%) | called by mutect2, pindel, varscan2
- ADD2 | c.1044C>T p.A348= | Silent (SNP) | VAF 54/202 reads (27%) | catalogued as rs376528363; called by muse, mutect2, varscan2
- ADGRL4 | c.1110T>C p.C370= | Silent (SNP) | VAF 83/233 reads (36%) | catalogued as COSV100876513; called by muse, mutect2, varscan2
- CCDC85A | c.1621A>C p.R541= | Silent (SNP) | VAF 28/80 reads (35%) | catalogued as COSV101339553; called by muse, mutect2, varscan2
- CD163 | c.2199G>A p.E733= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100776097; called by muse, mutect2, varscan2
- CNGA2 | c.1146G>T p.R382= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as COSV100323925; called by muse, varscan2
- DNAH10 | c.7707T>C p.T2569= (on ENST00000409039; = p.T2508= on NM_207437.3) | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV101292616; called by muse, mutect2, varscan2
- ECPAS | c.1530A>G p.R510= | Silent (SNP) | VAF 36/121 reads (30%) | catalogued as rs925107346, COSV99399177; called by muse, mutect2, varscan2
- FBXL7 | c.471C>T p.I157= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV100310709, COSV61653319; called by muse, mutect2, varscan2
- FCHSD1 | c.753C>G p.S251= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as COSV101447614; called by muse, mutect2, varscan2
- FYB1 | c.1320T>C p.D440= | Silent (SNP) | VAF 94/286 reads (33%) | catalogued as rs533406048, COSV100686261; called by muse, mutect2, varscan2
- H1-7 | c.351C>T p.A117= | Silent (SNP) | VAF 39/131 reads (30%) | catalogued as rs372377328; called by muse, mutect2, varscan2
- KALRN | c.4239G>A p.K1413= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV99567051; called by muse, mutect2, varscan2
- LFNG | c.393C>T p.D131= | Silent (SNP) | VAF 323/1042 reads (31%) | catalogued as rs984165635, COSV56069624; called by muse, varscan2
- LRRC32 | c.471G>A p.A157= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs1439220821, COSV99476752, COSV99477022; called by muse, mutect2, varscan2
- MAP3K6 | c.2187C>T p.S729= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as COSV100709433; called by muse, mutect2, varscan2
- MED24 | c.771A>G p.T257= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100673330; called by muse, mutect2, varscan2
- OR5M3 | c.670C>T p.L224= | Silent (SNP) | VAF 68/186 reads (37%) | catalogued as COSV100392678; called by muse, mutect2, varscan2
- PCLO | c.663G>A p.K221= | Silent (SNP) | VAF 8/150 reads (5%) | called by muse, mutect2
- RCOR2 | c.921C>T p.S307= | Silent (SNP) | VAF 25/72 reads (35%) | catalogued as rs1565160165, COSV100036345; called by muse, mutect2, varscan2
- RP1 | c.2310T>C p.V770= | Silent (SNP) | VAF 19/411 reads (5%) | catalogued as COSV99608691; called by muse, mutect2
- RPS6KA4 | c.1785G>A p.L595= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99590422; called by muse, mutect2, varscan2
- RTN4 | c.1359T>C p.G453= | Silent (SNP) | VAF 26/78 reads (33%) | catalogued as COSV100463875; called by muse, mutect2, varscan2
- SELENOP | c.192G>A p.L64= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs770721160, COSV101539875; called by muse, mutect2, varscan2
- SMARCD2 | c.876A>G p.G292= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV99856628; called by muse, mutect2, varscan2
- ZNF670 | c.642A>G p.E214= | Silent (SNP) | VAF 26/155 reads (17%) | catalogued as COSV100829340; called by muse, mutect2, varscan2
